Surgical pathology report (de-identified scan), TCGA case TCGA-G4-6302, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G4-6302-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

A. RIGHT COLON TERMINAL ILEUM

DIAGNOSIS:

RIGHT COLON AND TERMINAL ILEUM, HEMICOLECTOMY

- WELL DIFFERENTIATED ADENOCARCINOMA OF THE COLON (MUCINOUS TYPE), TRANSMURALLY INVASIVE WITH EXTENSION INTO ADJACENT SOFT TISSUES.
- TUBULOVILLOUS ADENOMA.
- FIFTEEN LYMPH NODES NEGATIVE FOR TUMOR (0/15).
- APPENDIX WITH NO SIGNIFICANT PATHOLOGIC ABNORMALITIES.
- TERMINAL ILEUM WITH NO SIGNIFICANT PATHOLOGIC FINDINGS.
- SURGICAL MARGINS OF EXCISION ARE NEGATIVE FOR TUMOR.

COLORECTAL CANCER TEMPLATE

Specimen Type:	Right hemicolectomy
Tumor Site:	Cecum
Tumor Configuration:	Exocytic
Tumor Size:	3.2x3.2x0.6
Histologic Type:	Adenocarcinoma, mucinous type - sections demonstrate infiltrating and dissecting pools of extracellular mucin, with associated tumor epithelium, consistent with a mucinous (colloid) carcinoma. Virtually all of the invasive tumor shows mucinous morphology.
Histologic Grade:	Well differentiated
Extent of Invasion:	Tumor invades through the muscularis propria into adjacent adipose tissue and focally extend to within 1 mm. of the radial margins.
Margins:	Negative
Venous/Lymphatic Invasion:	Present
Perineural Invasion:	Present
Additional Pathologic Findings:	The invasive cancer appears to be arising in the setting of a tubular villous adenoma
Extent of Resection:	0
Lymph Nodes:	Negative: 0/15
Implants:	Absent
EGFR Expression:	
Pathologic Stage:	T3 M0 MX

SPECIMEN(S):

A. RIGHT COLON TERMINAL ILEUM

CLINICAL HISTORY:

None given

GROSS DESCRIPTION:

A. RIGHT COLON TERMINAL ILEUM:

Specimen consists of a resected portion of terminal ileum and cecum measuring 15 cm. in length and circumference from varying from 4 cm. to 6 cm. An irregular polypoid lesion measuring 3.2x3.2x0.6 cm. is noted 6.5 cm. from the resected ileum margin and 7 cm. from the resected colonic margin. Appendix is identified and measures 3.2 cm. in length and 0.5 cm. in width. Representative sections are submitted as follows:

Cassette A1: distal margin

Cassette A2: proximal margin

Cassette A3-A7: sections through the polypoid tumor mass

Cassette A8: random sections of the ileum

Cassette A9-A10: random sections of the cecum close to the polypoid lesion

Cassette A11: terminal ileum

[page 2 of 2]
[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file e039c1ac-a062-4251-8161-e7a943656aa4 (TCGA-G4-6302.04AFF74D-07D3-4453-8D97-88AF7D64D787.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).